Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A1A1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A1A1-06A (Metastatic).

PATIENT HISTORY:

Rule out neck melanoma.

PRE-OP DIAGNOSIS:

POST-OP DIAGNOSIS:

PROCEDURE:

Right neck mass.

None given.

Right neck dissection.

ICD-0-3
Melanoma, NOS 8720/3
Site Code: Neck, NOS C44.4

12/15/10

**AMENDED/CORRECTED REPORT:**

This report is being issued at request of the surgeon
which consist of a right parotid and neck dissection.

to clarify the localization of the metastases in the specimen part 2,

This amendment reflects the

1. Following change: The location of the lymph nodes, with respect to periparotid or neck, was clarified.
2. In the diagnostic field
3. For the following reason: requested clarification about location of lymph nodes.
4. Communicated on

This Amended/Corrected Report supersedes all prior reports under this accession number and should be the only one used for patient management. All reports, both original and amended/corrected, are maintained in electronic archives and are available upon request.

FINAL DIAGNOSIS:

PART 1: NECK, RIGHT LEVEL 5, "MASS", EXCISION -
METASTATIC MELANOMA (2.3 CM) IN ONE LEVEL 5 LYMPH NODE (see comment).

- PART 2: LYMPH NODE AND PAROTID, RIGHT, NECK DISSECTION AND PAROTIDECTOMY -
- A. METASTATIC MELANOMA IN ONE OF ONE (1/1) RIGHT INTRAPAROTID LYMPH NODES (2.0 CM) WITH EXTRANODAL EXTENSION.
- B. PAROTID TISSUE WITH NO SPECIFIC PATHOLOGIC CHANGE.
- C. METASTATIC MELANOMA IN TWENTY-THREE OF FORTY-FOUR RIGHT NECK LYMPH NODES INVOLVING LEVELS 2 THROUGH 5 (23/44). LARGEST LYMPH NODE (1.9 CM) (LEVEL 3).
- D. EXTRANODAL EXTENSION IDENTIFIED.

COMMENT:

Immunohistochemical and special stains (see microscopic description) support the diagnosis of malignant melanoma.

MICROSCOPIC:**PARAFFIN SECTION IMMUNOHISTOCHEMISTRY**

Immunohistochemical stains were performed on Part 1C.
The following results were found:

Antigen/Antibody	Usual Reactivity	Result
Pankeratin	Cytokeratin	Negative.
S100/S100a	Neural, melanoma & other	Positive.
Melan-A		Focally positive.

HIFAA Discrepancy		

Source: NCI Genomic Data Commons file 1930b90d-8456-4f16-9a39-9b9e760e302b (TCGA-ER-A1A1.91EF4517-2AC4-4DF9-BD96-CF60236F350A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).